Somatic mutation profile of tumor specimen TCGA-20-1683-01A (aliquot TCGA-20-1683-01A-01W-0633-09) from TCGA case TCGA-20-1683, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.7 years (24,006 days).
Specimen TCGA-20-1683-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df5913b1-641c-42b5-9de3-6a2d104ba25a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-20-1683-10A (Blood Derived Normal), aliquot TCGA-20-1683-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a15143bf-bdce-48fa-b28a-631977662499

The open-access MAF lists 102 somatic variants for this specimen: 78 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 20, Intron 3, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 2, In Frame Ins 1, 3'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 195/202 reads (97%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA4 | c.4103G>A p.R1368H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs761163530, COSV64675771; called by muse, mutect2, varscan2
- ADGRG7 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56299350; called by muse, mutect2, varscan2
- ALDH3A1 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 59/66 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV56736250; called by muse, mutect2, varscan2
- ALPK2 | c.5255C>A p.S1752* | Nonsense Mutation (SNP) | VAF 14/264 reads (5%) | catalogued as COSV100864870, COSV64498116; called by muse, mutect2
- ALPK2 | c.5014C>G p.P1672A | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as COSV100864580, COSV100864873; called by muse, mutect2
- ARHGEF15 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 75/120 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV62725885, COSV62726836; called by muse, mutect2, varscan2
- ATL1 | c.877T>C p.F293L | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63297050; called by muse, mutect2, varscan2
- CPEB4 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV54174428; called by muse, mutect2, varscan2
- CSMD1 | c.10356A>T p.Q3452H (on ENST00000520002; = p.Q3451H on NM_033225.6) | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV59353905; called by muse, mutect2, varscan2
- CYP26A1 | c.1322G>C p.S441T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV56419210; called by muse, mutect2, varscan2
- CYP4F2 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 154/506 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50002073; called by muse, mutect2, varscan2
- DNMBP | c.3851A>G p.Y1284C | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1459115509, COSV60629772; called by muse, mutect2, varscan2
- DOP1B | c.6218T>G p.F2073C | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV67694658; called by muse, mutect2, varscan2
- E2F7 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 96/146 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59741983; called by muse, mutect2, varscan2
- EYA4 | c.107C>G p.A36G | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV62057494; called by muse, mutect2, varscan2
- FAM171B | c.749C>G p.P250R | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779368274, COSV59006219; called by muse, mutect2, varscan2
- FOXJ3 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as rs377432876; called by muse, mutect2, varscan2
- GABRG2 | c.819A>T p.R273S (on ENST00000361925 / NM_001375343.1; = p.R233S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.991); catalogued as COSV62720372; called by muse, mutect2, varscan2
- GATB | c.752C>A p.A251E | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99859373; called by muse, mutect2
- GOSR2 | c.116A>G p.K39R (on ENST00000393456 / NM_001321134.1; = p.K57R on NM_004287.5) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1396367618, COSV56663527; called by muse, mutect2, varscan2
- H2BC10 | c.5C>G p.P2R | Missense Mutation (SNP) | VAF 89/187 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs762462418, COSV59953409; called by muse, mutect2, varscan2
- KALRN | c.4646G>A p.G1549E | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53773903; called by muse, mutect2, varscan2
- KCNA6 | c.613G>C p.G205R | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV54976503; called by muse, mutect2, varscan2
- KIAA0930 | c.336G>A p.K112= (on ENST00000336156 / NM_001009880.2; = p.K117= on NM_015264.2) | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as COSV52664369; called by muse, mutect2, varscan2
- KIAA1210 | c.3491G>T p.R1164M | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV68178704; called by muse, mutect2, varscan2
- LEPR | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV60759811; called by muse, mutect2, varscan2
- LRRN2 | c.2069G>T p.W690L | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV100912808, COSV100912984; called by muse, mutect2
- MAGEC1 | c.1746G>T p.Q582H | Missense Mutation (SNP) | VAF 966/1406 reads (69%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.948); catalogued as COSV53577548, COSV99594763; called by muse, mutect2, varscan2
- MCTS1 | c.510A>T p.L170F | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64892751; called by muse, mutect2, varscan2
- MNAT1 | c.809G>C p.G270A | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV54193701; called by muse, mutect2, varscan2
- MTA2 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV53471214; called by muse, mutect2, varscan2
- MUC17 | c.7471A>C p.T2491P | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100075238; called by muse, mutect2
- NBAS | c.6316C>G p.R2106G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs553094685, COSV55731015, COSV55742684; called by muse, mutect2, varscan2
- NBAS | c.4399C>G p.L1467V | Missense Mutation (SNP) | VAF 180/656 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV55731024; called by muse, mutect2, varscan2
- OPA1 | c.2617C>T p.R873W (on ENST00000361510 / NM_130837.3; = p.R818W on NM_015560.3) | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143252541, COSV100655350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR51A7 | c.275T>G p.I92S | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63788698; called by muse, mutect2, varscan2
- PEX16 | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53803194; called by muse, mutect2, varscan2
- PPP2R2B | c.976C>T p.R326C (on ENST00000394409; = p.R392C on NM_181674.2) | Missense Mutation (SNP) | VAF 200/611 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1019612179, COSV60772067; called by muse, mutect2, varscan2
- PTBP2 | c.193C>T p.P65S (on ENST00000426398 / NM_001300986.2; = p.P57S on NM_021190.4) | Missense Mutation (SNP) | VAF 74/138 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV64625702; called by muse, mutect2, varscan2
- PTCH1 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV100110143, COSV59489466; called by muse, mutect2
- PTGIS | c.1470C>G p.H490Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.095); catalogued as COSV54834956, COSV99721344; called by muse, mutect2
- RIN2 | c.2141A>G p.Y714C (on ENST00000255006 / NM_001242581.1; = p.Y665C on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54791399; called by muse, mutect2, varscan2
- RLF | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.236); catalogued as COSV101035737; called by muse, mutect2
- RNF20 | c.1072A>C p.T358P | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV66661840; called by muse, mutect2, varscan2
- RRP12 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs762936931, COSV59669854; called by muse, mutect2
- SCARF1 | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV53960092; called by muse, mutect2, varscan2
- SCG2 | c.1663A>C p.S555R | Missense Mutation (SNP) | VAF 130/429 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV59541092; called by muse, mutect2, varscan2
- SCN3A | c.4417C>A p.Q1473K | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV51817758; called by muse, mutect2, varscan2
- SELENBP1 | c.482G>C p.G161A | Missense Mutation (SNP) | VAF 111/578 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV64373860; called by muse, mutect2, varscan2
- SEMA3A | c.2087C>T p.T696I | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as COSV54880670; called by muse, mutect2, varscan2
- SENP2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs145156187; called by muse, mutect2, varscan2
- SKAP2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1025140851, COSV61725796; called by muse, mutect2, varscan2
- SLA | c.673T>C p.F225L (on ENST00000338087 / NM_001045556.3; = p.F265L on NM_006748.4) | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99603518; called by muse, mutect2
- SLC25A23 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757635721, COSV51190293; called by muse, mutect2, varscan2
- SLCO3A1 | c.1091T>C p.V364A | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.981); catalogued as COSV59233936; called by muse, mutect2, varscan2
- SMAD4 | c.928T>C p.F310L | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV61686806; called by muse, mutect2, varscan2
- SPTA1 | c.737G>C p.W246S | Missense Mutation (SNP) | VAF 71/384 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100935555, COSV63756940; called by muse, mutect2, varscan2
- ST18 | c.2830G>T p.E944* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV52500608, COSV52502438; called by muse, mutect2, varscan2
- TAGAP | c.466G>C p.V156L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV57852664; called by muse, mutect2
- TDRD5 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 127/782 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.145); catalogued as COSV54247095; called by muse, mutect2, varscan2
- TENM3 | c.3568G>A p.D1190N | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs905498465, COSV69299405; called by muse, mutect2
- TM4SF20 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 148/549 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58819183; called by muse, mutect2, varscan2
- TMEM30A | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 127/136 reads (93%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57875212; called by muse, mutect2, varscan2
- WDR55 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 5/131 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV100298332; called by muse, mutect2
- ZKSCAN4 | c.547G>C p.G183R | Missense Mutation (SNP) | VAF 110/470 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV66023795; called by muse, mutect2, varscan2
- ZNF18 | c.1575T>G p.C525W | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59551971; called by muse, mutect2, varscan2
- ZNF449 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.113); catalogued as COSV100203085; called by muse, mutect2, varscan2
- ZNF699 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58025160; called by muse, mutect2, varscan2
- ZP4 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs772372321, COSV100850773, COSV63912858; called by muse, mutect2, varscan2
- ZSCAN31 | c.775A>G p.R259G | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100717163; called by muse, mutect2
- COX11 | c.62_73dup p.H21_S24dup | In Frame Ins (INS) | VAF 27/67 reads (40%) | called by mutect2, varscan2
- ERG | c.1232dup p.E412Gfs*61 (on ENST00000398919 / NM_001243428.1; = p.E388Gfs*61 on NM_004449.4) | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by pindel, varscan2
- NLRP14 | c.2462+1G>C p.X821_splice | Splice Site (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- PLCXD3 | c.213del p.K71Nfs*7 | Frame Shift Del (DEL) | VAF 52/163 reads (32%) | called by mutect2, pindel, varscan2
- SLC22A9 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2
- WDR55 | c.522_523del p.M174Ifs*24 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | called by mutect2, pindel, varscan2
- ZNF311 | c.1326C>G p.H442Q | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.099); called by muse, mutect2
- ABCC1 | c.2961G>T p.V987= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV60690432; called by muse, mutect2, varscan2
- ALK | c.1026T>C p.S342= | Silent (SNP) | VAF 41/189 reads (22%) | catalogued as rs958346511, COSV66580804; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC85A | c.1653A>T p.G551= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV68153889; called by muse, mutect2, varscan2
- DCLRE1C | c.1962C>T p.P654= (on ENST00000378278 / NM_001350965.2; = p.P539= on NM_022487.4) | Silent (SNP) | VAF 86/434 reads (20%) | catalogued as COSV57954891; called by muse, mutect2, varscan2
- DOCK1 | c.4044C>T p.F1348= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV54737482, COSV54744531; called by muse, mutect2
- FBN1 | c.258G>T p.R86= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as rs930004823, COSV100356517; called by muse, mutect2
- FBXL3 | c.951A>G p.R317= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100842400; called by muse, mutect2
- LARP4B | c.1320C>T p.F440= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as COSV100295734; called by muse, mutect2
- LONRF3 | c.1776A>G p.R592= (on ENST00000371628 / NM_001031855.3; = p.R551= on NM_024778.5) | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV59155084; called by muse, mutect2, varscan2
- LRRFIP1 | c.1317C>T p.A439= (on ENST00000392000 / NM_001137552.2; = p.A415= on NM_004735.4) | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as COSV99791333; called by muse, mutect2, varscan2
- PACS1 | c.726T>C p.S242= | Silent (SNP) | VAF 41/147 reads (28%) | catalogued as COSV57698943; called by muse, mutect2, varscan2
- RREB1 | c.2052C>T p.A684= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs916815830, COSV58561842; called by muse, mutect2, varscan2
- RYR2 | c.7992G>C p.L2664= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100773165; called by muse, mutect2
- SERPINB2 | c.1068C>T p.H356= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV53074461; called by muse, mutect2, varscan2
- TAS2R38 | c.321C>T p.L107= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as COSV71885277; called by muse, mutect2, varscan2
- TMEM120B | c.522G>A p.R174= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1366291769, COSV61184999; called by muse, mutect2, varscan2
- TNK2 | c.12G>A p.E4= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1038297849, COSV57373329; called by muse, mutect2, varscan2
- TRRAP | c.630A>C p.R210= | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as COSV62850253; called by muse, mutect2, varscan2
- TYSND1 | c.1576C>T p.L526= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV54643650; called by muse, mutect2, varscan2
- WNT5A | c.939G>A p.E313= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV52838592; called by muse, mutect2, varscan2
- CFAP57 | c.1929+46C>T | Intron (SNP) | VAF 159/532 reads (30%) | catalogued as COSV65265058; called by muse, mutect2, varscan2
- CSH1 | c.*1G>T | 3'UTR (SNP) | VAF 32/102 reads (31%) | catalogued as rs774698420, COSV100298469; called by muse, mutect2, varscan2
- DAPK3 | c.630-290C>T | Intron (SNP) | VAF 4/11 reads (36%) | catalogued as COSV56663918; called by muse, mutect2, varscan2
- MECR | c.756+512G>C | Intron (SNP) | VAF 14/39 reads (36%) | catalogued as COSV55286652; called by muse, mutect2, varscan2
